Somatic mutation profile of tumor specimen TCGA-DD-A11B-01A (aliquot TCGA-DD-A11B-01A-11D-A12Z-10) from TCGA case TCGA-DD-A11B, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.5 years (26,857 days).
Specimen TCGA-DD-A11B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3220aec5-226f-45f4-ae44-b72d845c4032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A11B-10A (Blood Derived Normal), aliquot TCGA-DD-A11B-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/075ca860-dff5-476d-ba45-ab06416424ef

The open-access MAF lists 59 somatic variants for this specimen: 42 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 16, Frame Shift Del 5, Nonsense Mutation 3, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALAD | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs778238328, COSV52959978; called by muse, mutect2, varscan2
- APOBEC4 | c.747T>A p.N249K | Missense Mutation (SNP) | VAF 171/654 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.157); catalogued as COSV58018169; called by muse, mutect2, varscan2
- BRD4 | c.3241C>T p.H1081Y | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54591014; called by muse, mutect2, varscan2
- C1orf226 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.399); catalogued as rs1226576898, COSV63396257; called by muse, mutect2, varscan2
- C3 | c.4177C>G p.R1393G | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV55577665; called by muse, mutect2, varscan2
- CCDC40 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.055); catalogued as COSV53902260; called by muse, mutect2, varscan2
- CEP128 | c.3132G>T p.W1044C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV55384893; called by muse, mutect2, varscan2
- CLTC | c.1192A>G p.I398V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52245787; called by muse, mutect2, varscan2
- EEF1A1 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV58549515; called by muse, mutect2, varscan2
- EEF1A1 | c.1294A>T p.T432S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV58548569, COSV58549078; called by muse, mutect2, varscan2
- HERC1 | c.11759A>G p.N3920S | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV71249284; called by muse, mutect2
- KAZN | c.51G>C p.Q17H | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV65722734; called by muse, mutect2, varscan2
- KIF21A | c.5021A>G p.N1674S (on ENST00000361418 / NM_001378440.1; = p.N1661S on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.97); catalogued as COSV62775444; called by muse, mutect2, varscan2
- KMT2B | c.919T>C p.F307L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs540162147, COSV52891735; called by muse, mutect2, varscan2
- MFSD3 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV56742264; called by muse, mutect2, varscan2
- MIS12 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 9/102 reads (9%) | catalogued as COSV50147692; called by muse, mutect2
- MTM1 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 99/114 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs781984239, COSV60336614; called by muse, mutect2, varscan2
- MUC2 | c.1015del p.V339Cfs*17 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | catalogued as COSV100363662; called by mutect2, pindel, varscan2
- OGG1 | c.186A>C p.Q62H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57354255; called by muse, mutect2, varscan2
- PCDH11Y | c.271A>T p.T91S (on ENST00000400457 / NM_032973.2; = p.T80S on NM_032971.3) | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53086759; called by muse, mutect2
- PLAC8L1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.031); catalogued as COSV61014222; called by muse, mutect2, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | catalogued as rs772701630; called by mutect2, varscan2
- RGL3 | c.770T>A p.L257H | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63387203; called by muse, mutect2, varscan2
- RNF216 | c.1989-1G>T p.X663_splice (on ENST00000425013 / NM_207116.3; = p.X720_splice on NM_207111.4) | Splice Site (SNP) | VAF 40/87 reads (46%) | catalogued as COSV66291862; called by muse, mutect2, varscan2
- S1PR3 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778344408, COSV63980999; called by muse, mutect2, varscan2
- SALL1 | c.3878C>T p.P1293L | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV51761534; called by muse, mutect2, varscan2
- SESTD1 | c.296A>G p.K99R | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV70568192; called by muse, mutect2, varscan2
- SH2D5 | c.95G>A p.G32D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1270056124; called by muse, mutect2
- SLC2A6 | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767052534, COSV52470842; called by muse, mutect2, varscan2
- SLITRK3 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53851301; called by muse, mutect2, varscan2
- SSRP1 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104376672, COSV53480633; called by muse, mutect2, varscan2
- STAR | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52418104; called by muse, mutect2, varscan2
- TRAK2 | c.2639T>A p.L880* | Nonsense Mutation (SNP) | VAF 50/121 reads (41%) | catalogued as COSV60273798; called by muse, mutect2, varscan2
- TRPC1 | c.2323A>G p.I775V (on ENST00000476941 / NM_001251845.2; = p.I741V on NM_003304.4) | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV56427891; called by muse, mutect2, varscan2
- TSC22D1 | c.2234C>T p.P745L | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV71776036; called by muse, mutect2, varscan2
- TTC14 | c.55T>G p.S19A | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56013258; called by muse, mutect2, varscan2
- TTC24 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV63998063, COSV63998180; called by muse, mutect2, varscan2
- VANGL2 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1182443634, COSV63604705; called by muse, mutect2, varscan2
- VEZF1 | c.1232C>G p.T411S | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.157); catalogued as COSV51969623; called by muse, mutect2, varscan2
- AXIN1 | c.1326del p.A443Lfs*37 | Frame Shift Del (DEL) | VAF 9/10 reads (90%) | called by mutect2, varscan2
- LAMB4 | c.2969_2970del p.E990Vfs*54 | Frame Shift Del (DEL) | VAF 54/181 reads (30%) | called by pindel, varscan2
- ZNF676 | c.390del p.Y130* (on ENST00000650058; = p.Y98* on NM_001001411.3) | Frame Shift Del (DEL) | VAF 68/175 reads (39%) | called by mutect2, pindel, varscan2
- C6 | c.237C>T p.P79= | Silent (SNP) | VAF 74/173 reads (43%) | catalogued as CD961874, COSV54711307, COSV54714263; called by muse, mutect2, varscan2
- ENTPD3 | c.181C>T p.L61= | Silent (SNP) | VAF 65/149 reads (44%) | catalogued as COSV57195609; called by muse, mutect2, varscan2
- EPHA2 | c.837A>G p.G279= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV64454085; called by muse, mutect2
- HDAC10 | c.438G>T p.V146= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV53134433; called by muse, mutect2
- MAST1 | c.1443G>T p.T481= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV52251257; called by muse, mutect2, varscan2
- MORN3 | c.180C>T p.A60= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as COSV62507670; called by muse, mutect2, varscan2
- OVCH1 | c.3000T>C p.S1000= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV58966094; called by muse, mutect2, varscan2
- PHB2 | c.273C>T p.S91= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs782246503, COSV54643187; called by muse, mutect2, varscan2
- RAB2A | c.222G>T p.S74= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV52913133; called by muse, mutect2, varscan2
- SLC12A7 | c.1302C>T p.I434= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs746691377, COSV53760134; called by muse, mutect2
- SOX6 | c.2202A>T p.P734= (on ENST00000528429 / NM_001145819.2; = p.P707= on NM_017508.3) | Silent (SNP) | VAF 56/117 reads (48%) | catalogued as COSV57052807; called by muse, mutect2, varscan2
- SREBF1 | c.2229C>T p.S743= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs1326222654, COSV55417839, COSV55418473; called by muse, mutect2, varscan2
- STK11 | c.843G>A p.P281= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs756095270, CD982962, COSV58821884, COSV58823674, COSV58823877; ClinVar: likely benign; called by muse, mutect2, varscan2
- STYXL2 | c.1326C>T p.S442= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs756297966, COSV54808057; called by muse, mutect2, varscan2
- SYT8 | c.186C>A p.L62= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV53290493; called by muse, mutect2, varscan2
- ZNF302 | c.153A>G p.P51= (on ENST00000627982; = p.P50= on NM_018443.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as COSV71063760; called by muse, mutect2, varscan2
- GDF5 | c.-398+683A>G | Intron (SNP) | VAF 40/153 reads (26%) | catalogued as COSV100699061; called by muse, mutect2, varscan2
